Somatic mutation profile of tumor specimen PCProject_0381_T2_WES (aliquot PCProject_0381_T2_WES_1) from CMI case PCProject_0381, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 47.7 years (17,434 days).
Specimen PCProject_0381_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6310a671-b2eb-4cd0-923c-c053f31aa39a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0381_SALIVA (DNA), aliquot PCProject_0381_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43b231b5-a50f-40ff-b377-f6cba69c3125

The open-access MAF lists 21 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, RNA 3, 5'UTR 1, Intron 1, 3'UTR 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCFL | c.1570C>T p.R524* | Nonsense Mutation (SNP) | VAF 20/138 reads (14%) | catalogued as rs1205889847, COSV54773106; called by muse, mutect2, varscan2
- GGA2 | c.801C>T p.V267= | Splice Region (SNP) | VAF 18/204 reads (9%) | catalogued as rs367831044, COSV59169939; called by muse, mutect2
- PPP1R9A | c.2407G>A p.V803M | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.898); catalogued as COSV56883415; called by muse, mutect2
- SCN10A | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs145909172; called by muse, mutect2
- ALPI | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- CARMIL2 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, varscan2
- CEP295 | c.1600T>G p.L534V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2
- SORBS1 | c.2470A>G p.K824E (on ENST00000361941 / NM_001034954.2; = p.K474E on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- WNK2 | c.6500A>G p.D2167G (on ENST00000297954 / NM_001282394.1; = p.D2130G on NM_006648.3) | Missense Mutation (SNP) | VAF 55/390 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ZC3H12C | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- ATP2B2 | c.948G>A p.A316= (on ENST00000352432; = p.A327= on NM_001001331.4) | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as rs139919641; called by muse, mutect2
- B4GALNT4 | c.1542G>A p.P514= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1448386027, COSV100327439; called by muse, mutect2, varscan2
- CKAP5 | c.1365C>T p.V455= | Silent (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- ERC1 | c.1696T>C p.L566= (on ENST00000360905 / NM_178040.4; = p.L538= on NM_178039.4) | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as rs1475260399; called by muse, mutect2, varscan2
- PPP1R3C | c.882G>A p.P294= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs1234288556; called by muse, mutect2, varscan2
- AC244258.1 | n.635C>T | RNA (SNP) | VAF 11/109 reads (10%) | catalogued as rs768649530; called by muse, mutect2, varscan2
- ARID4B | c.-17T>C | 5'UTR (SNP) | VAF 20/258 reads (8%) | catalogued as rs764874176; called by muse, mutect2
- CASP8 | c.306-1935G>A | Intron (SNP) | VAF 23/234 reads (10%) | catalogued as rs774427459; called by muse, mutect2, varscan2
- DCHS2 | n.8405A>T | RNA (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- SNORD115-31 | n.44G>A | RNA (SNP) | VAF 30/276 reads (11%) | called by muse, mutect2, varscan2
- TRIM23 | c.*339C>G | 3'UTR (SNP) | VAF 20/182 reads (11%) | catalogued as COSV51553454, COSV99140304; called by muse, mutect2, varscan2
